Somatic mutation profile of tumor specimen TCGA-06-0188-01A (aliquot TCGA-06-0188-01A-01W-0254-08) from TCGA case TCGA-06-0188, project TCGA-GBM (Glioblastoma Multiforme). Sex at birth: male; Vital status: Dead; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 71.4 years (26,080 days).
Specimen TCGA-06-0188-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) dd38645a-bec0-4074-bf4c-76ee92336680.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-06-0188-10B (Blood Derived Normal), aliquot TCGA-06-0188-10B-01D-1491-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/cd827e34-1dc9-4b86-bd2e-6b437db18cdf

The open-access MAF lists 21 somatic variants for this specimen: 16 protein-altering or splice-affecting, 4 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 9, Silent 4, Frame Shift Ins 4, Frame Shift Del 2, RNA 1, Translation Start Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PTEN | c.968del p.N323Mfs*21 | Frame Shift Del (DEL) | VAF 47/89 reads (53%) | catalogued as rs121913291; ClinVar: likely pathogenic / pathogenic; called by mutect2, pindel, varscan2
- ADAM23 | c.2340dup p.K781Qfs*3 | Frame Shift Ins (INS) | VAF 6/29 reads (21%) | catalogued as rs767549806; called by mutect2, varscan2
- COL14A1 | c.2536C>T p.R846C | Missense Mutation (SNP) | VAF 14/56 reads (25%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs560701039, COSV52850114, COSV52867933; called by muse, mutect2, varscan2
- EIF3B | c.1085dup p.E363Rfs*18 | Frame Shift Ins (INS) | VAF 6/22 reads (27%) | catalogued as rs764010445; called by mutect2, varscan2
- GTPBP8 | c.432dup p.P145Tfs*27 | Frame Shift Ins (INS) | VAF 4/26 reads (15%) | catalogued as rs1443988894; called by pindel, varscan2
- ITGAM | c.926G>A p.R309H | Missense Mutation (SNP) | VAF 8/31 reads (26%) | SIFT tolerated (0.26); PolyPhen benign (0.003); catalogued as rs759107498, COSV54933370, COSV54936492; called by muse, mutect2, varscan2
- MYH8 | c.1397C>T p.A466V | Missense Mutation (SNP) | VAF 19/29 reads (66%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs554419599, COSV67963918; called by muse, mutect2, varscan2
- NADK2 | c.1123T>A p.F375I (on ENST00000381937 / NM_001085411.3; = p.F212I on NM_153013.4) | Missense Mutation (SNP) | VAF 16/36 reads (44%) | SIFT deleterious (0); PolyPhen benign (0.196); catalogued as COSV56936182; called by muse, varscan2
- OR4K5 | c.736del p.V246* | Frame Shift Del (DEL) | VAF 65/368 reads (18%) | catalogued as COSV100262410, COSV60003280; called by mutect2, pindel, varscan2
- PASD1 | c.3G>T p.M1? | Translation Start Site (SNP) | VAF 7/9 reads (78%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.026); catalogued as COSV100949533, COSV64855005; called by muse, varscan2
- PRUNE2 | c.41G>A p.R14Q | Missense Mutation (SNP) | VAF 5/11 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs745663522, COSV65027512; called by muse, mutect2
- RYR2 | c.1240C>T p.R414C | Missense Mutation (SNP) | VAF 6/45 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.795); catalogued as rs764698152, CM065449, COSV63677117, COSV63693384; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SLC5A7 | c.1196C>T p.T399M | Missense Mutation (SNP) | VAF 6/23 reads (26%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.631); catalogued as rs748755332, COSV50891064; called by muse, mutect2, varscan2
- UGT2B11 | c.445T>C p.F149L | Missense Mutation (SNP) | VAF 22/49 reads (45%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV71423268; called by muse, mutect2, varscan2
- UGT2B28 | c.1262C>T p.S421L | Missense Mutation (SNP) | VAF 6/32 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.91); catalogued as rs371664274, COSV59430439; called by muse, mutect2, varscan2
- HEATR4 | c.907_908insCT p.E303Afs*34 | Frame Shift Ins (INS) | VAF 4/30 reads (13%) | called by mutect2, varscan2
- ITGAM | c.741G>A p.K247= | Silent (SNP) | VAF 4/17 reads (24%) | catalogued as COSV54936482; called by muse, mutect2
- KMT2C | c.1227T>C p.C409= | Silent (SNP) | VAF 9/20 reads (45%) | catalogued as COSV51479437; called by muse, mutect2, varscan2
- MMP26 | c.699C>T p.H233= | Silent (SNP) | VAF 7/34 reads (21%) | catalogued as rs778728830, COSV56172078; called by muse, mutect2, varscan2
- TTN | c.37539A>G p.K12513= (on ENST00000591111; = p.K5089= on NM_003319.4) | Silent (SNP) | VAF 9/18 reads (50%) | catalogued as rs1042532845, COSV60239359; called by muse, mutect2, varscan2
- TMEM183B | n.362A>G | RNA (SNP) | VAF 13/20 reads (65%) | called by muse, mutect2, varscan2
